Somatic mutation profile of tumor specimen TCGA-D8-A1Y1-01A (aliquot TCGA-D8-A1Y1-01A-21D-A14K-09) from TCGA case TCGA-D8-A1Y1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 80.7 years (29,474 days).
Specimen TCGA-D8-A1Y1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d39832d-a7ff-404f-ad6d-382dd98890fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1Y1-10A (Blood Derived Normal), aliquot TCGA-D8-A1Y1-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a4f5e5b-d795-4ab9-9dcf-15f0b3cad9c9

The open-access MAF lists 236 somatic variants for this specimen: 183 protein-altering or splice-affecting, 52 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 52, Frame Shift Del 41, Nonsense Mutation 11, In Frame Del 4, Frame Shift Ins 3, Splice Site 3, Nonstop Mutation 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- JAG1 | c.439+1G>A p.X147_splice | Splice Site (SNP) | VAF 13/93 reads (14%) | catalogued as rs863223648, CS003182, COSV54755405, COSV54757371; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 29/47 reads (62%) | catalogued as rs63750508, CM960990, COSV51878201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 42/67 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA10 | c.2255G>A p.W752* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV52230000; called by muse, mutect2, varscan2
- ACP7 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58700902; called by muse, mutect2, varscan2
- ACSM2A | c.1098G>A p.T366= (on ENST00000219054; = p.T287= on NM_001308169.2) | Splice Region (SNP) | VAF 10/75 reads (13%) | catalogued as rs759143815, COSV54590075; called by muse, mutect2, varscan2
- ADAMTS13 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs587693885, COSV63021323; called by muse, mutect2, varscan2
- ADGRL3 | c.2753C>T p.S918F (on ENST00000506720 / NM_001322402.2; = p.S850F on NM_015236.6) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV72231996; called by muse, mutect2, varscan2
- ALX4 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765208460, COSV61324766; called by muse, mutect2, varscan2
- ANK2 | c.3032G>A p.R1011H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563808779, COSV52144383; called by muse, mutect2, varscan2
- ANKIB1 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs191723687; called by muse, mutect2, varscan2
- ANKLE2 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs889582581, COSV61711796; called by muse, mutect2, varscan2
- AOC3 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs368244449; called by muse, mutect2, varscan2
- AP1B1 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.086); catalogued as rs1308644175, COSV58023638; called by muse, mutect2, varscan2
- APMAP | c.945del p.Y316Tfs*29 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs777444320; called by mutect2, pindel
- ARFGAP3 | c.981A>G p.I327M | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99605035; called by muse, mutect2
- ARHGEF5 | c.3620G>A p.R1207Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as rs755202652, COSV50215133; called by mutect2, varscan2
- ATP7B | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs368381292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AVPR1B | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782061896, COSV65637835; called by muse, mutect2, varscan2
- BABAM2 | c.851+1G>A p.X284_splice | Splice Site (SNP) | VAF 36/106 reads (34%) | catalogued as COSV59617839, COSV59626067; called by muse, mutect2, varscan2
- BDP1 | c.7666C>T p.R2556* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as rs746088956, COSV62432459; called by muse, mutect2, varscan2
- C12orf40 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs190784791, COSV61130026; called by mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 40/141 reads (28%) | catalogued as rs760711956; called by mutect2, varscan2
- CCDC66 | c.1795A>G p.T599A (on ENST00000394672 / NM_001353147.1; = p.T565A on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV58309698; called by muse, mutect2, varscan2
- CCDC97 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV54191715; called by muse, varscan2
- CDH1 | c.1936+1G>T p.X646_splice | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV55730906, COSV55731485; called by muse, mutect2, varscan2
- CEP85L | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs140573157; called by muse, mutect2, varscan2
- CFAP251 | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV56612460; called by muse, mutect2, varscan2
- CHD7 | c.7184C>A p.S2395Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV101417939; called by muse, mutect2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs754415052; called by mutect2, varscan2
- CLSTN3 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs755463631; called by muse, mutect2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | catalogued as rs777945397; called by mutect2, varscan2
- CREBBP | c.5357G>A p.R1786H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs988251457, COSV99268149; called by muse, mutect2
- CRP | c.263A>G p.D88G | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54814827; called by muse, mutect2, varscan2
- CSPP1 | c.3235C>A p.P1079T (on ENST00000676605; = p.P1038T on NM_024790.6) | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV51592891; called by muse, mutect2, varscan2
- DCP2 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as COSV66618334; called by muse, mutect2, varscan2
- DIMT1 | c.761del p.N254Tfs*12 | Frame Shift Del (DEL) | VAF 36/128 reads (28%) | catalogued as rs757109196; called by mutect2, pindel, varscan2
- DLG2 | c.1978C>T p.R660* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as rs747209072, COSV54641039; called by muse, mutect2, varscan2
- DNAH9 | c.10600C>T p.R3534* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs61736773, COSV52377717; called by muse, mutect2, varscan2
- DNAJC3 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.124); catalogued as rs778884455, COSV65132796; called by muse, mutect2, varscan2
- DNAJC7 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57269870; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs782552436; called by pindel, varscan2
- DPYSL2 | c.1189del p.R397Gfs*95 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as COSV60783627; called by mutect2, pindel, varscan2
- EGFLAM | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148322152, COSV59311196; called by muse, mutect2, varscan2
- EHD2 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV54411034; called by muse, mutect2, varscan2
- EIF4E2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs375938541; called by muse, mutect2, varscan2
- EIF4G3 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1183533925, COSV51694669; called by muse, mutect2, varscan2
- EP400 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200268785, COSV57786957, COSV57789869; called by muse, mutect2, varscan2
- EPPK1 | c.5521C>T p.Q1841* | Nonsense Mutation (SNP) | VAF 27/244 reads (11%) | catalogued as COSV73262394; called by muse, mutect2, varscan2
- EPX | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs151055641; called by muse, mutect2, varscan2
- ERICH3 | c.4478C>T p.A1493V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV58618844; called by mutect2, varscan2
- EXOC2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100032411; called by muse, mutect2, varscan2
- FCRL5 | c.1516C>G p.Q506E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV62512620, COSV62520536; called by muse, mutect2, varscan2
- FLOT2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs376080270; called by muse, mutect2, varscan2
- GCN1 | c.3531G>T p.Q1177H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100324471; called by muse, mutect2
- GLB1L2 | c.1733T>C p.I578T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV57000872; called by muse, mutect2, varscan2
- GMPS | c.1783G>C p.A595P | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55812130; called by muse, mutect2, varscan2
- GNA14 | c.809A>T p.N270I | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59029724; called by muse, mutect2, varscan2
- GRXCR1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs201948629; called by muse, mutect2, varscan2
- HERC1 | c.13876G>A p.V4626M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs368472341; called by mutect2, varscan2
- HRC | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV53258936; called by muse, mutect2, varscan2
- HSD17B4 | c.1066A>G p.K356E (on ENST00000414835 / NM_001199291.3; = p.K331E on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV56339274; called by muse, mutect2, varscan2
- HSP90AB1 | c.1655A>T p.K552M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs756933263, COSV100806874; called by muse, mutect2
- ICAM3 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV50330194; called by muse, mutect2, varscan2
- ICAM3 | c.162T>A p.S54R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50330205; called by muse, mutect2, varscan2
- IGHD | c.478_479del p.E160Vfs*36 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs775849668; called by pindel, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- KCNAB3 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV58141147; called by muse, mutect2, varscan2
- KIAA1109 | c.5476C>T p.R1826* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs1027018806, COSV52692964; called by muse, mutect2, varscan2
- KIRREL3 | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101585517; called by muse, mutect2
- KRT7 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs367997288; called by mutect2, varscan2
- L1CAM | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as rs782479917, COSV62830242; called by muse, mutect2, varscan2
- LCT | c.3916G>A p.D1306N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489231732, COSV51544059; called by muse, mutect2
- LRRC30 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV67302347; called by muse, mutect2, varscan2
- LSM11 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs763310569, COSV53847875; called by muse, mutect2, varscan2
- MAP2K4 | c.516del p.D173Tfs*24 | Frame Shift Del (DEL) | VAF 39/88 reads (44%) | catalogued as COSV62260982; called by mutect2, pindel, varscan2
- MARCHF5 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1445346247, COSV62768901; called by muse, mutect2, varscan2
- MARK2 | c.1307G>A p.R436Q (on ENST00000402010 / NM_001039469.2; = p.R435Q on NM_004954.5) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs368859674, COSV100158209; called by muse, mutect2, varscan2
- MC4R | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55353096; called by muse, mutect2, varscan2
- MCM7 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374121810; called by muse, mutect2, varscan2
- MED1 | c.2672A>G p.D891G | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100327240; called by muse, mutect2
- MED25 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV57207551; called by muse, mutect2, varscan2
- MEF2D | c.1566A>G p.*522Wext*11 | Nonstop Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as rs1484869298, COSV61730487; called by muse, mutect2, varscan2
- MRPS18C | c.43_45del p.K15del | In Frame Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs745400793; called by pindel, varscan2
- MRTFB | c.2863C>T p.R955W (on ENST00000571589 / NM_001365412.2; = p.R905W on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767875492, COSV57961932; called by muse, mutect2, varscan2
- MTG1 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as COSV58155251; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | catalogued as rs767880823; called by mutect2, varscan2
- MYH3 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs943488185, COSV56867669; called by muse, mutect2, varscan2
- MYO18A | c.4888C>T p.R1630W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757050642, COSV62873642; called by muse, mutect2, varscan2
- NLRP2 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs1165160519, COSV54760616; called by muse, mutect2, varscan2
- NOL4L | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62890335; called by muse, mutect2, varscan2
- NUMA1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs763169605, COSV61183291; called by muse, mutect2, varscan2
- OBSCN | c.12973G>A p.V4325M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs746674168, COSV52748776; called by muse, mutect2, varscan2
- OR13C4 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52927102, COSV52928603; called by muse, mutect2, varscan2
- OR4F6 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs769055061, COSV61027123; called by muse, mutect2, varscan2
- OR51A4 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs150732161, COSV100985301; called by muse, mutect2, varscan2
- PAPPA | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs570712795, COSV60280087; called by muse, mutect2, varscan2
- PCDHA4 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV63544559, COSV63546254; called by muse, mutect2, varscan2
- PCDHGA10 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs778441176, COSV53989655; called by mutect2, varscan2
- PCDHGA4 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as rs764054199, COSV53967053; called by muse, mutect2, varscan2
- PDZD2 | c.7204G>A p.E2402K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1479682163, COSV56852172; called by muse, mutect2, varscan2
- PHTF1 | c.1637dup p.M547Hfs*10 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | catalogued as rs750248180; called by mutect2, varscan2
- PLXNA2 | c.2848A>G p.T950A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.307); catalogued as COSV65445119; called by muse, mutect2, varscan2
- PPP2CB | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV55328853; called by muse, mutect2, varscan2
- PPP2R3C | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54835235; called by muse, mutect2, varscan2
- PROC | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764737827, COSV52165297; called by muse, mutect2, varscan2
- PRR14 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV54913878; called by muse, mutect2, varscan2
- PSPC1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 88/133 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58891099, COSV58891264; called by muse, mutect2, varscan2
- RAD21 | c.1130C>G p.A377G | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.978); catalogued as COSV52064309; called by muse, mutect2, varscan2
- RAD50 | c.2059G>T p.V687F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs1561642416, COSV99528437; called by muse, mutect2, varscan2
- RAD54L2 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs532971546, COSV56577291; called by muse, mutect2, varscan2
- RARS1 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555837551, COSV51566134; called by muse, mutect2, varscan2
- RGS16 | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100842488, COSV62375956; called by muse, mutect2, varscan2
- RPGRIP1 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763392584, COSV52855809; called by muse, mutect2, varscan2
- SDK1 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs377301442; called by mutect2, varscan2
- SDR9C7 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs141626978; called by mutect2, varscan2
- SERPING1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs548701651, COSV53544424; called by muse, mutect2, varscan2
- SFMBT2 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748945625, COSV62811148, COSV62811907; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 27/220 reads (12%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC35G6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV59496209; called by muse, mutect2, varscan2
- SLC5A7 | c.499_501del p.I167del | In Frame Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs766537447; called by pindel, varscan2
- SPACA1 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV52761535; called by muse, mutect2, varscan2
- SRSF11 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV63937877; called by muse, mutect2, varscan2
- ST6GAL2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | PolyPhen possibly damaging (0.514); catalogued as COSV64527764; called by muse, mutect2, varscan2
- SULF2 | c.676del p.H226Tfs*43 | Frame Shift Del (DEL) | VAF 40/113 reads (35%) | catalogued as rs774011241, COSV63414163; called by mutect2, pindel, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs770033147; called by mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | catalogued as rs753462162; called by mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs750901207; called by mutect2, pindel, varscan2
- TANC2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1480252971, COSV67341890; called by muse, mutect2, varscan2
- TAS2R3 | c.203del p.L68* | Frame Shift Del (DEL) | VAF 27/171 reads (16%) | catalogued as rs770618229; called by mutect2, pindel, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D31 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); catalogued as COSV54871212; called by muse, mutect2, varscan2
- TCEAL6 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as COSV65654288; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs758822980; called by mutect2, varscan2
- TFPI | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.44); catalogued as rs746176720, COSV51905918; called by muse, mutect2, varscan2
- TLR7 | c.2402C>T p.T801M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV66125635; called by muse, mutect2, varscan2
- TMEM139 | c.625del p.Y209Mfs*10 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as rs769384623; called by mutect2, pindel, varscan2
- TMEM259 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs776235651, COSV99312063; called by muse, varscan2
- TMEM63A | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760750326, COSV64764204; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs781830688; called by mutect2, varscan2
- TMIGD1 | c.650_651del p.V217Gfs*25 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | catalogued as rs1414861469; called by pindel, varscan2
- TNS1 | c.4143C>A p.S1381R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50771754; called by muse, mutect2, varscan2
- TOX3 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs573103587, COSV54873504; called by muse, mutect2, varscan2
- TP53I3 | c.533T>A p.L178H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as COSV99272518; called by muse, mutect2
- TPSD1 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs200938484; called by muse, mutect2, varscan2
- TRIM35 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.073); catalogued as rs1238011630, COSV59524124; called by muse, varscan2
- TRIM56 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs973659137, COSV60157965, COSV60161518; called by muse, mutect2, varscan2
- TRMT13 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV64502526; called by muse, mutect2, varscan2
- UBTD2 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV67144087; called by muse, mutect2, varscan2
- UBTF | c.1682T>C p.M561T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.191); catalogued as rs1474551826, COSV57188547; called by muse, mutect2, varscan2
- VRK3 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57468054; called by muse, mutect2, varscan2
- XIRP1 | c.3319G>T p.G1107C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV61141478; called by muse, mutect2, varscan2
- XPC | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99541978; called by muse, mutect2, varscan2
- YTHDC2 | c.3842C>T p.S1281L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs144091848; called by muse, mutect2, varscan2
- ZAR1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779795445, COSV51955531; called by muse, mutect2, varscan2
- ZBTB20 | c.2155G>A p.V719I (on ENST00000474710 / NM_001164342.2; = p.V646I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.984); catalogued as rs779910215, COSV61856059; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs563751025; called by mutect2, varscan2
- ZNF512 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV62678421; called by muse, mutect2, varscan2
- ZPLD1 | c.787G>A p.V263I (on ENST00000466937 / NM_001329788.1; = p.V279I on NM_175056.2) | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs186547877, COSV60356004; called by muse, mutect2, varscan2
- ABCB6 | c.810del p.L271Sfs*20 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- AC008676.3 | c.340del p.W114Gfs*3 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, varscan2
- CD1E | c.993del p.K331Nfs*47 | Frame Shift Del (DEL) | VAF 27/159 reads (17%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- KIF5B | c.1864del p.M622Wfs*8 | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- KLK1 | c.561dup p.A188Sfs*26 | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- KMT2A | c.11474del p.K3825Rfs*31 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- MDN1 | c.1323del p.F441Lfs*7 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, varscan2
- PCLO | c.3927_3929del p.E1309del | In Frame Del (DEL) | VAF 21/190 reads (11%) | called by pindel, varscan2
- PLCL1 | c.2526del p.F842Lfs*4 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- PTCHD3 | c.1084del p.I362Lfs*3 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- RAPGEF2 | c.1551del p.V518* | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- RASGRP4 | c.1809del p.G604Efs*57 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- SNAPC1 | c.639del p.F213Lfs*7 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- SPEN | c.7484del p.P2495Lfs*4 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- SYNE3 | c.2222G>T p.R741M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- SYT8 | c.340del p.D114Mfs*25 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- ZEB2 | c.3412_3414del p.K1138del | In Frame Del (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- ABTB1 | c.348C>T p.D116= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs779438995, COSV51743007; called by muse, mutect2, varscan2
- ACE | c.612C>T p.Y204= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs773489735, COSV52013329; called by muse, mutect2, varscan2
- AHCTF1 | c.2175A>G p.S725= (on ENST00000366508; = p.S699= on NM_015446.5) | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV58255964; called by muse, mutect2, varscan2
- ANKRD50 | c.1968C>T p.H656= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs976922473, COSV101538863; called by muse, mutect2
- ATP8B1 | c.1248T>C p.S416= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV52180419; called by muse, mutect2, varscan2
- BBS5 | c.231G>A p.L77= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV54754387; called by muse, mutect2, varscan2
- C1QTNF2 | c.705C>T p.G235= (on ENST00000393975; = p.G190= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs200309696, COSV67433360; called by muse, mutect2, varscan2
- CAV3 | c.132G>A p.V44= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV57481015; called by muse, mutect2, varscan2
- CCDC88C | c.1800G>A p.T600= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs774165990, COSV66241870; called by muse, mutect2, varscan2
- CFH | c.1284A>G p.T428= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV62776089, COSV62778745; called by muse, mutect2, varscan2
- CMYA5 | c.12030C>T p.G4010= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs945824386, COSV101405627; called by muse, mutect2, varscan2
- CPT1B | c.324C>T p.S108= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56419129; called by muse, mutect2, varscan2
- DNAJC13 | c.57A>G p.S19= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV53458544; called by muse, mutect2, varscan2
- DPYD | c.990G>A p.S330= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1441537394, COSV64615287; called by muse, mutect2, varscan2
- EML2 | c.627G>A p.L209= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV55604206; called by muse, mutect2, varscan2
- FADS2 | c.390C>T p.H130= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs142843367; called by muse, mutect2, varscan2
- FAM47C | c.324G>A p.S108= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV63730584; called by muse, mutect2, varscan2
- GRIN2B | c.2064C>T p.N688= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs748606750, COSV74206340; called by muse, mutect2, varscan2
- GUK1 | c.444G>A p.R148= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV57158370; called by muse, mutect2, varscan2
- HAGH | c.372C>T p.Y124= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs750712106, COSV68400964, COSV68401250; called by mutect2, varscan2
- HDAC11 | c.900C>A p.T300= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs377587104, COSV55474603; called by muse, mutect2, varscan2
- HMCN1 | c.7521A>G p.P2507= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV54942964; called by muse, mutect2, varscan2
- ITFG2 | c.501G>A p.L167= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV57391151; called by muse, mutect2, varscan2
- KBTBD4 | c.492G>T p.T164= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55456360; called by muse, mutect2, varscan2
- KCNF1 | c.1113C>T p.V371= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs771906770, COSV99705448; called by muse, mutect2, varscan2
- KIRREL2 | c.2076A>G p.P692= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV52880192; called by muse, mutect2, varscan2
- MAN2B2 | c.198C>T p.R66= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs779997292, COSV53454200; called by muse, mutect2, varscan2
- MRPS18B | c.321C>T p.I107= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV52542658; called by muse, mutect2, varscan2
- MT1M | c.39C>T p.C13= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs199506795, COSV65835980; called by muse, mutect2, varscan2
- NAPRT | c.948C>T p.G316= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs150227030; called by mutect2, varscan2
- OPTN | c.1257C>T p.D419= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV53813351; called by muse, mutect2, varscan2
- OR8G1 | c.231T>C p.I77= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV100422161; called by muse, mutect2, varscan2
- PARD6A | c.903G>C p.G301= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99537308; called by muse, mutect2, varscan2
- PCDHGA7 | c.2331C>T p.D777= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV54037333; called by muse, mutect2, varscan2
- PEAK3 | c.69G>A p.T23= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs781519940, COSV59702521; called by mutect2, varscan2
- PIK3CA | c.210C>T p.F70= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs760094170, COSV55908704, COSV55941259; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLD6 | c.582C>T p.Y194= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs142631639; called by muse, mutect2, varscan2
- PNLIPRP1 | c.105C>T p.G35= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs781876317, COSV62613567; called by muse, mutect2, varscan2
- POMK | c.627G>A p.P209= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs771102494, COSV58858678; called by muse, mutect2, varscan2
- PRPF4 | c.1549C>T p.L517= (on ENST00000374198 / NM_001322267.2; = p.L518= on NM_004697.5) | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV65253477; called by muse, mutect2, varscan2
- PXDN | c.2184C>T p.R728= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs766598025, COSV53236754, COSV53242874; called by muse, mutect2, varscan2
- RAB39B | c.186C>T p.I62= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1477697422, COSV65625232; called by muse, mutect2, varscan2
- RNF14 | c.936G>A p.P312= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs141694109, COSV61662332, COSV61663043; called by muse, mutect2, varscan2
- SVOP | c.1305G>A p.A435= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs575951583, COSV54469177; called by muse, mutect2, varscan2
- TAF2 | c.2484C>T p.L828= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV100978771, COSV65421300; called by muse, mutect2, varscan2
- TDRD10 | c.786C>T p.H262= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs768018563, COSV52726417; called by muse, mutect2, varscan2
- TPH2 | c.135C>T p.D45= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs74510566, COSV61590555; called by muse, mutect2, varscan2
- TRIM38 | c.1257G>A p.E419= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV62642960; called by muse, mutect2, varscan2
- TTC23L | c.789G>A p.Q263= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV72205907, COSV72205981; called by muse, mutect2, varscan2
- UGT2A1 | c.919C>T p.L307= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as COSV54146682; called by muse, mutect2, varscan2
- USH2A | c.14904C>T p.D4968= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs151165599, COSV56358752; called by muse, mutect2
- ZBTB16 | c.1197C>T p.S399= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV60099835; called by muse, mutect2, varscan2
- IGHV1-12 | n.160C>T | RNA (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
